Somatic mutation profile of tumor specimen TCGA-86-8073-01A (aliquot TCGA-86-8073-01A-11D-2238-08) from TCGA case TCGA-86-8073, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.1 years (21,214 days).
Specimen TCGA-86-8073-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecb0ff77-09f2-45fe-aa40-9e02aa7b988a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8073-10A (Blood Derived Normal), aliquot TCGA-86-8073-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a250294-e760-418a-bed3-be259ae161e1

The open-access MAF lists 1,588 somatic variants for this specimen: 1,192 protein-altering or splice-affecting, 367 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,038, Silent 367, Nonsense Mutation 83, Splice Site 30, Frame Shift Del 22, RNA 15, Intron 9, Frame Shift Ins 9, Splice Region 6, 5'UTR 2, In Frame Del 2, 3'UTR 2.

Variants (750 of 1,588; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN1 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 96/497 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746125212, CM950272, COSV58367156; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PROKR2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138672528, CM083838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2071G>T p.V691L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99288242; called by muse, mutect2, varscan2
- ABCA13 | c.4980G>C p.L1660F | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV101329987; called by muse, mutect2, varscan2
- ABCC8 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100216935; called by muse, mutect2, varscan2
- ABL2 | c.281G>T p.R94M (on ENST00000502732 / NM_007314.4; = p.R79M on NM_005158.5) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772605; called by muse, mutect2, varscan2
- AC100868.1 | c.937T>A p.C313S | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225647; called by muse, mutect2
- ACTL7A | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100453060; called by muse, mutect2, varscan2
- ACTR6 | c.562A>T p.I188L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV99498541; called by muse, mutect2, varscan2
- ACTRT1 | c.597C>G p.S199R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100947537, COSV64420124; called by muse, mutect2, varscan2
- ADAM18 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.51); catalogued as COSV99695255; called by muse, mutect2, varscan2
- ADAM23 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV100007151; called by muse, mutect2, varscan2
- ADAM29 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100821951; called by muse, mutect2, varscan2
- ADAM29 | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100821952; called by muse, mutect2, varscan2
- ADAM33 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597768; called by muse, mutect2, varscan2
- ADAM8 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV101291643; called by muse, varscan2
- ADAMTS12 | c.3231C>A p.S1077R | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs756957050, COSV61255799, COSV61256233; called by muse, mutect2, varscan2
- ADAMTS15 | c.407T>G p.I136S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100143243; called by muse, mutect2, varscan2
- ADAMTS16 | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99940672; called by muse, mutect2, varscan2
- ADAMTS2 | c.2727C>A p.N909K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99281547; called by muse, mutect2, varscan2
- ADAMTS4 | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV100917393; called by muse, mutect2, varscan2
- ADAMTS4 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100917394; called by muse, varscan2
- ADAMTS5 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99537337; called by muse, mutect2, varscan2
- ADARB1 | c.2190G>T p.K730N (on ENST00000360697 / NM_001346687.2; = p.K690N on NM_001112.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100653692; called by muse, mutect2, varscan2
- ADCY1 | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99811658; called by muse, mutect2, varscan2
- ADCY1 | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV99811660; called by muse, mutect2
- ADCYAP1R1 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100416367; called by muse, mutect2, varscan2
- ADD2 | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100035178, COSV52458363; called by muse, mutect2
- ADGRB3 | c.1766T>C p.M589T | Missense Mutation (SNP) | VAF 72/596 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101000249; called by muse, mutect2, varscan2
- ADGRB3 | c.3035+2T>A p.X1012_splice | Splice Site (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99484372; called by muse, mutect2
- ADGRL4 | c.1034C>A p.P345H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV100875787; called by muse, mutect2, varscan2
- ADGRV1 | c.5927A>G p.Y1976C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs1317686063, COSV101315692; called by muse, mutect2
- AEBP1 | c.1629C>A p.A543= | Splice Region (SNP) | VAF 9/116 reads (8%) | catalogued as COSV99788597; called by muse, mutect2
- AEBP1 | c.2194C>A p.R732S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.154); catalogued as COSV99788599; called by muse, mutect2, varscan2
- AFDN | c.4706G>A p.R1569K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100652741; called by muse, mutect2
- AGO2 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99595490, COSV99596793; called by muse, mutect2, varscan2
- AHNAK2 | c.16585C>A p.H5529N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100316652; called by muse, mutect2, varscan2
- AHNAK2 | c.15230C>A p.A5077E | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV100316655; called by muse, mutect2, varscan2
- AHNAK2 | c.11443G>T p.V3815L | Missense Mutation (SNP) | VAF 101/640 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100316656; called by muse, mutect2, varscan2
- AHNAK2 | c.9347C>T p.P3116L | Missense Mutation (SNP) | VAF 68/429 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs750311433; called by muse, mutect2, varscan2
- AKAP8 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV99511811; called by muse, varscan2
- AKR1B1 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 45/491 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV99605216; called by muse, mutect2
- AKR7A2 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 21/182 reads (12%) | catalogued as COSV99351986; called by muse, mutect2, varscan2
- AL121899.2 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101198424; called by muse, mutect2, varscan2
- ALDH16A1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs569748998, COSV99512738; called by muse, mutect2, varscan2
- ALDH3A1 | c.716A>T p.N239I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855807; called by muse, mutect2, varscan2
- AMER3 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100366258; called by muse, mutect2, varscan2
- AMIGO2 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99873529; called by muse, mutect2, varscan2
- AMMECR1L | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99761315; called by muse, mutect2, varscan2
- AMPD2 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1276920640, COSV104374875, COSV99857526; called by muse, mutect2, varscan2
- ANGPT4 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV101124682, COSV67920896; called by muse, mutect2, varscan2
- ANGPTL5 | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100527724; called by muse, mutect2, varscan2
- ANK1 | c.4751C>G p.S1584C | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV99224644; called by muse, mutect2, varscan2
- ANK1 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV99224647; called by muse, mutect2, varscan2
- ANKFN1 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100593315; called by muse, mutect2, varscan2
- ANKRD30A | c.3811G>T p.G1271* (on ENST00000611781; = p.G1215* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100653201, COSV100654067; called by muse, mutect2
- ANKRD33 | c.29G>T p.S10I (on ENST00000340970 / NM_001304459.2; = p.S145I on NM_182608.4) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100001199; called by muse, mutect2, varscan2
- ANKRD40 | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560437; called by muse, mutect2, varscan2
- ANKRD42 | c.1111A>T p.R371* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as COSV99473655; called by muse, mutect2, varscan2
- ANKS6 | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758020659, COSV100782251; called by muse, mutect2, varscan2
- ANO5 | c.1788G>T p.W596C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61089374; called by muse, mutect2, varscan2
- AP1G1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100250232; called by muse, mutect2, varscan2
- APBA1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV99595750; called by muse, mutect2
- APBA1 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as rs777762976, COSV99595752; called by muse, mutect2
- APOB | c.10465T>C p.Y3489H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99264702; called by muse, mutect2
- APOB | c.9758T>C p.V3253A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs1304430624, COSV99264703; called by muse, mutect2, varscan2
- APP | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100695514; called by muse, mutect2, varscan2
- APPL1 | c.285+1G>T p.X95_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99897544; called by muse, mutect2, varscan2
- AQP10 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 34/200 reads (17%) | catalogued as COSV100270067; called by muse, mutect2, varscan2
- ARAP1 | c.3737A>G p.H1246R (on ENST00000393609 / NM_001040118.2; = p.H1001R on NM_015242.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as COSV100501713, COSV61989183; called by muse, mutect2
- ARFGEF2 | c.2730G>T p.Q910H | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100904167; called by muse, mutect2, varscan2
- ARFRP1 | c.240A>T p.E80D | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99422853; called by muse, mutect2, varscan2
- ARHGAP12 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761960205, COSV100260497; called by muse, mutect2, varscan2
- ARHGAP19 | c.408G>T p.L136F | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57395045; called by muse, mutect2, varscan2
- ARHGAP29 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs771049716, COSV53115461; called by muse, mutect2, varscan2
- ARHGAP32 | c.1318C>T p.H440Y (on ENST00000310343 / NM_001378025.1; = p.H91Y on NM_014715.4) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100087371; called by muse, mutect2, varscan2
- ARHGEF10L | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV99392452; called by muse, mutect2, varscan2
- ARHGEF10L | c.2172-1G>T p.X724_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99392455; called by muse, mutect2, varscan2
- ARHGEF18 | c.3274C>A p.P1092T (on ENST00000359920 / NM_001130955.2; = p.P988T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100149283; called by muse, mutect2, varscan2
- ARID1B | c.2611G>T p.G871* | Nonsense Mutation (SNP) | VAF 33/207 reads (16%) | catalogued as rs1554226036, COSV99268246; called by muse, mutect2, varscan2
- ARID4A | c.2294A>G p.N765S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100794126; called by muse, mutect2, varscan2
- ARMCX2 | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100168089; called by muse, mutect2, varscan2
- ARNT | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1407040981, COSV100591036; called by muse, mutect2, varscan2
- ASAH1 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV100025616; called by muse, mutect2, varscan2
- ASB10 | c.1225C>A p.Q409K (on ENST00000420175 / NM_001142459.2; = p.Q394K on NM_080871.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV99318412; called by muse, mutect2, varscan2
- ASPM | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV99659962; called by muse, mutect2, varscan2
- ASTN1 | c.3640G>T p.G1214C | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100705949; called by muse, mutect2, varscan2
- ASTN1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 23/131 reads (18%) | catalogued as COSV56083103, COSV99920980; called by muse, mutect2, varscan2
- ASXL3 | c.2798G>T p.R933L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52456646, COSV99324128; called by muse, mutect2, varscan2
- ASXL3 | c.5362G>T p.G1788C | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as COSV99324130; called by muse, mutect2, varscan2
- ATF7IP | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99661398; called by muse, mutect2
- ATP10A | c.2012G>T p.S671I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV100791034; called by muse, mutect2, varscan2
- ATP11A | c.1704A>T p.T568= | Splice Region (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99367957; called by muse, mutect2, varscan2
- ATP12A | c.1424C>A p.S475* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV54524817, COSV99517269; called by muse, mutect2, varscan2
- ATP13A2 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100454015; called by muse, mutect2, varscan2
- ATP1A2 | c.2581G>T p.G861C | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100767712; called by muse, mutect2, varscan2
- ATP2C1 | c.2058-1G>T p.X686_splice | Splice Site (SNP) | VAF 20/130 reads (15%) | catalogued as CS000061, CS101650, COSV100146510; called by muse, mutect2, varscan2
- ATP9A | c.2605G>T p.V869F | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100124618, COSV104408827; called by muse, mutect2, varscan2
- AXDND1 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544858689, COSV100858294; called by muse, mutect2, varscan2
- AXDND1 | c.937C>G p.R313G | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV100858295; called by muse, mutect2, varscan2
- B3GALNT1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100251969; called by muse, mutect2, varscan2
- BAALC | c.492C>A p.S164R (on ENST00000297574 / NM_001364874.1; = p.S129R on NM_024812.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV99883332; called by muse, mutect2, varscan2
- BAIAP3 | c.1764G>T p.Q588H | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV99136159; called by muse, varscan2
- BAZ2B | c.5683G>A p.G1895R | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV100600506; called by muse, mutect2, varscan2
- BAZ2B | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); catalogued as COSV100600507; called by muse, varscan2
- BCAN | c.2486G>T p.R829L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100227979; called by muse, mutect2, varscan2
- BCAS4 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV99372380; called by muse, mutect2, varscan2
- BDP1 | c.3071A>T p.K1024M | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100702883; called by muse, mutect2, varscan2
- BEND3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs782316621, COSV100944575, COSV64682063; called by muse, mutect2
- BFSP2 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100183666; called by muse, mutect2, varscan2
- BICD1 | c.2736G>T p.K912N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.624); catalogued as COSV99862212; called by muse, mutect2, varscan2
- BICD1 | c.2737G>T p.E913* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as rs1217882321, COSV99862214; called by muse, mutect2, varscan2
- BNC1 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 24/178 reads (13%) | catalogued as COSV100597034; called by muse, mutect2, varscan2
- BNC2 | c.1862A>T p.H621L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101032628; called by muse, mutect2, varscan2
- BPTF | c.8846C>T p.A2949V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100074497; called by muse, mutect2, varscan2
- BRINP2 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100837952; called by muse, mutect2, varscan2
- C12orf50 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV100072119; called by muse, mutect2, varscan2
- C1QL3 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as rs1260391937, COSV100126973, COSV54348074; called by muse, mutect2, varscan2
- C2orf16 | c.2345T>C p.I782T | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs373095066; called by muse, mutect2, varscan2
- C3orf62 | c.395_396del p.E132Vfs*27 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | catalogued as rs767159892; called by pindel, varscan2
- C9orf135 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs756449792, COSV101019781; called by muse, mutect2, varscan2
- CACNA1D | c.2546C>T p.S849L (on ENST00000350061 / NM_001128840.3; = p.S869L on NM_000720.4) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs776897309, COSV99857340; called by muse, mutect2, varscan2
- CACNA1E | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV62401402, COSV62409708; called by muse, mutect2
- CACNA1E | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100701694; called by muse, mutect2
- CACNA1G | c.5327G>T p.C1776F | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100661497; called by muse, mutect2, varscan2
- CACNA1H | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs772246879, COSV100671577; called by muse, mutect2, varscan2
- CACNA1I | c.2291C>A p.T764N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100359751; called by muse, mutect2, varscan2
- CACNA2D3 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99871922; called by muse, mutect2
- CACNA2D4 | c.1479C>G p.D493E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99765367; called by muse, mutect2
- CACNG2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV100268664; called by muse, mutect2, varscan2
- CADPS | c.637A>T p.K213* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99337005; called by muse, mutect2, varscan2
- CALCOCO2 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99363721; called by muse, mutect2, varscan2
- CALCR | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100810456; called by muse, mutect2
- CAMK2D | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs1300916212, COSV99593631; called by muse, mutect2, varscan2
- CARD9 | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 119/584 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047001; called by muse, mutect2, varscan2
- CASQ1 | c.1068C>A p.S356R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63623553; called by muse, varscan2
- CASR | c.1934A>T p.N645I (on ENST00000490131; = p.N722I on NM_000388.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV99948717; called by muse, mutect2, varscan2
- CASR | c.2494A>T p.T832S (on ENST00000490131; = p.T909S on NM_000388.4) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.017); catalogued as COSV99948718; called by muse, mutect2, varscan2
- CBLN4 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99290436; called by muse, mutect2, varscan2
- CCDC136 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV52802720, COSV99922416; called by muse, mutect2, varscan2
- CCDC14 | c.2140A>T p.K714* (on ENST00000488653; = p.K666* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100113059; called by muse, mutect2, varscan2
- CCDC142 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99282050; called by muse, mutect2, varscan2
- CCDC171 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99900184; called by muse, mutect2, varscan2
- CCIN | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as COSV100631775; called by muse, mutect2, varscan2
- CCNB3 | c.1911G>T p.Q637H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV99328763; called by muse, mutect2, varscan2
- CCNB3 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52076063, COSV99328764; called by muse, mutect2, varscan2
- CCR5 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201179081; called by muse, mutect2, varscan2
- CD180 | c.1159T>A p.C387S | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842166; called by muse, mutect2, varscan2
- CD93 | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV99849040; called by muse, mutect2
- CDH10 | c.2239T>A p.S747T | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV100050759; called by muse, mutect2, varscan2
- CDH11 | c.1250T>A p.I417K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV51752275, COSV99217763; called by muse, mutect2, varscan2
- CDH12 | c.1856C>A p.A619E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101201434; called by muse, mutect2, varscan2
- CDH17 | c.1244C>A p.T415N | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99217189; called by muse, mutect2, varscan2
- CDH5 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100439140; called by muse, mutect2, varscan2
- CDH5 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100439142; called by muse, mutect2, varscan2
- CDH7 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.959); catalogued as COSV100541861; called by muse, mutect2, varscan2
- CDH9 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50253534, COSV99141291; called by muse, mutect2, varscan2
- CDH9 | c.2310G>C p.W770C | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142613; called by muse, mutect2, varscan2
- CDH9 | c.1655G>C p.R552P | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as COSV99142617; called by muse, mutect2
- CDK5RAP2 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV100575279; called by muse, mutect2, varscan2
- CELSR1 | c.5297G>T p.G1766V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV53094355, COSV99417556; called by muse, mutect2, varscan2
- CENPE | c.1866A>T p.Q622H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV99477455; called by muse, mutect2, varscan2
- CEP126 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.136); catalogued as COSV54827461, COSV99680849; called by muse, mutect2, varscan2
- CERS3 | c.409T>A p.W137R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99431662; called by muse, mutect2, varscan2
- CFAP61 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.255); catalogued as COSV99844105; called by muse, mutect2, varscan2
- CFAP65 | c.1778A>G p.D593G | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100444883; called by muse, mutect2
- CGB1 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV100031581; called by muse, mutect2, varscan2
- CHAT | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 73/501 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339960; called by muse, mutect2, varscan2
- CHD5 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99313082; called by muse, mutect2, varscan2
- CHTOP | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.264); catalogued as COSV100904630; called by muse, mutect2, varscan2
- CIB4 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99994698; called by muse, mutect2, varscan2
- CIDEB | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.691); catalogued as COSV99350583; called by muse, mutect2, varscan2
- CLCN1 | c.907T>A p.W303R | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM076105, COSV100577899; called by muse, mutect2, varscan2
- CLCNKB | c.1410G>T p.G470= | Splice Region (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100990221; called by muse, mutect2, varscan2
- CLEC10A | c.922C>A p.L308M (on ENST00000254868 / NM_182906.4; = p.L284M on NM_006344.4) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.144); catalogued as COSV99644636; called by muse, mutect2, varscan2
- CLEC6A | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as COSV101165627; called by muse, mutect2, varscan2
- CLSTN2 | c.2128C>A p.Q710K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV101515627; called by muse, mutect2, varscan2
- CMA1 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99157196; called by muse, mutect2, varscan2
- CNBD1 | c.385A>T p.R129* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101572854; called by muse, mutect2, varscan2
- CNKSR1 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100836720; called by muse, mutect2, varscan2
- CNKSR3 | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.132); catalogued as COSV101401317; called by muse, mutect2, varscan2
- CNOT4 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 10/115 reads (9%) | catalogued as COSV100211297; called by muse, mutect2
- CNTLN | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1384048227, COSV99263423; called by muse, mutect2, varscan2
- CNTN5 | c.942A>T p.K314N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99675039; called by muse, mutect2, varscan2
- CNTNAP2 | c.3007A>G p.K1003E | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as CM157852, COSV62267920; called by muse, mutect2, varscan2
- CNTNAP5 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV101443254; called by muse, mutect2, varscan2
- CNTNAP5 | c.2782G>T p.G928* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as rs866817882, COSV101443255; called by muse, mutect2, varscan2
- CNTNAP5 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101442888, COSV101443256; called by muse, mutect2, varscan2
- COBL | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV99471945; called by muse, mutect2, varscan2
- COL11A2 | c.4132G>A p.G1378S (on ENST00000341947 / NM_080680.3; = p.G1271S on NM_080679.2) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385941422, COSV100553664; called by muse, mutect2, varscan2
- COL12A1 | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100485685; called by muse, mutect2, varscan2
- COL14A1 | c.1551G>C p.M517I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.696); catalogued as COSV52871304; called by muse, mutect2, varscan2
- COL15A1 | c.3594A>T p.P1198= | Splice Region (SNP) | VAF 8/97 reads (8%) | catalogued as COSV100897538, COSV66647811; called by muse, mutect2
- COL1A1 | c.4237G>A p.D1413N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs72656349, CD1514959, CM062524, COSV99866786; called by muse, mutect2, varscan2
- COL22A1 | c.4372T>A p.S1458T | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as COSV100277374; called by muse, mutect2, varscan2
- COL22A1 | c.2159G>A p.G720D | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277376, COSV57330125; called by muse, mutect2, varscan2
- COL24A1 | c.3627A>T p.P1209= | Splice Region (SNP) | VAF 10/54 reads (19%) | catalogued as rs752620036, COSV100993100, COSV65306281; called by muse, mutect2, varscan2
- COL27A1 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100620866; called by muse, mutect2
- COL3A1 | c.952-1G>T p.X318_splice | Splice Site (SNP) | VAF 15/190 reads (8%) | catalogued as COSV100482755; called by muse, mutect2
- COL3A1 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482756; called by muse, mutect2
- COL6A3 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99797120; called by muse, mutect2, varscan2
- COL9A3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1370495778, COSV59651878; called by muse, mutect2, varscan2
- COL9A3 | c.793-1G>C p.X265_splice | Splice Site (SNP) | VAF 15/125 reads (12%) | catalogued as COSV100673338; called by muse, mutect2, varscan2
- COLEC11 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.974); catalogued as COSV99363044; called by muse, mutect2
- COP1 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as COSV100443033, COSV100444048; called by muse, mutect2, varscan2
- COPS5 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 31/253 reads (12%) | catalogued as COSV100769914, COSV63474902; called by muse, mutect2, varscan2
- CPS1 | c.1790C>A p.S597* | Nonsense Mutation (SNP) | VAF 7/163 reads (4%) | catalogued as CM114327, COSV99242570; called by muse, mutect2
- CPZ | c.1926C>G p.S642R (on ENST00000360986 / NM_001014447.3; = p.S631R on NM_003652.3) | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59924842; called by muse, mutect2
- CR1 | c.5201A>T p.K1734M | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65460874; called by muse, mutect2, varscan2
- CRACD | c.3008C>G p.P1003R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs1344458249, COSV51719285, COSV99948927; called by muse, varscan2
- CRY2 | c.1487G>T p.S496I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV101314569; called by muse, mutect2, varscan2
- CSMD1 | c.1238G>T p.G413V (on ENST00000520002; = p.G412V on NM_033225.6) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68178448, COSV68230838; called by muse, mutect2, varscan2
- CSMD2 | c.7729G>T p.G2577C | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99587990; called by muse, mutect2, varscan2
- CSMD3 | c.1705G>A p.D569N (on ENST00000297405 / NM_001363185.1; = p.D465N on NM_052900.3) | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99829795, COSV99846956; called by muse, mutect2
- CSTA | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99138647; called by muse, mutect2, varscan2
- CTCFL | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99712394; called by muse, mutect2, varscan2
- CTNNA2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63559921; called by muse, mutect2, varscan2
- CTNNA3 | c.2509A>T p.S837C | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV101041316; called by muse, mutect2, varscan2
- CTNND2 | c.1484C>A p.P495Q | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100474311; called by muse, mutect2
- CTSC | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV57059415; called by muse, mutect2, varscan2
- CTSV | c.303del p.K102Rfs*25 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | catalogued as COSV99414299; called by mutect2, pindel, varscan2
- CTTNBP2NL | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV99599875; called by muse, mutect2, varscan2
- CUBN | c.9619G>T p.E3207* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100912354, COSV64715276; called by muse, mutect2, varscan2
- CUEDC1 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as COSV100804700; called by muse, mutect2, varscan2
- CUX2 | c.3970G>T p.G1324C | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99918727; called by muse, mutect2, varscan2
- CYBB | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.229); catalogued as CM001658, COSV101059722; called by muse, mutect2, varscan2
- CYBB | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101059723, COSV66085391, COSV66085499; called by muse, mutect2, varscan2
- CYP2C18 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99608395; called by muse, mutect2
- CYP4F3 | c.1268G>C p.S423T | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99658006, COSV99658674; called by muse, mutect2
- DAB1 | c.1461G>C p.Q487H (on ENST00000371231; = p.Q454H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100976230, COSV64689669; called by muse, mutect2, varscan2
- DACT1 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100241719, COSV60022681; called by muse, mutect2, varscan2
- DBH | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); catalogued as COSV99707986; called by muse, mutect2, varscan2
- DCAF12L1 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421394, COSV64422944; called by muse, mutect2, varscan2
- DCAF12L1 | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100948183; called by muse, mutect2
- DCDC1 | c.5338C>G p.H1780D (on ENST00000597505 / NM_001367979.1; = p.H887D on NM_020869.3) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.025); catalogued as COSV100360394; called by muse, mutect2, varscan2
- DCHS1 | c.869T>A p.V290E | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100201827; called by muse, mutect2, varscan2
- DDHD2 | c.269A>C p.D90A | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101240582; called by muse, mutect2, varscan2
- DDI1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV100158512; called by muse, mutect2
- DDX10 | c.1801G>T p.G601* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100489255; called by muse, mutect2
- DDX20 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV63831119; called by muse, mutect2, varscan2
- DDX23 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV100339722; called by muse, mutect2, varscan2
- DDX60L | c.2366G>T p.G789V | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs368624817, COSV99487007, COSV99487270; called by muse, mutect2, varscan2
- DEFB116 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV101269218; called by muse, mutect2, varscan2
- DENND2A | c.2900A>T p.Q967L | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.244); catalogued as COSV99325844; called by muse, mutect2, varscan2
- DENND2A | c.2633A>T p.E878V | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV99325848; called by muse, mutect2, varscan2
- DENND2C | c.1951G>A p.D651N (on ENST00000393274 / NM_001256404.2; = p.D594N on NM_198459.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV101283908; called by muse, mutect2, varscan2
- DERL1 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99418383; called by muse, mutect2, varscan2
- DGKB | c.2234G>T p.C745F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99337940; called by muse, mutect2, varscan2
- DHX58 | c.1837A>T p.R613W | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99288122; called by muse, mutect2, varscan2
- DIO2 | c.123G>T p.L41F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101375843; called by muse, mutect2, varscan2
- DISC1 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99697484; called by muse, mutect2, varscan2
- DKKL1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV99678645; called by muse, mutect2, varscan2
- DLG5 | c.3080G>T p.R1027M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV100967356; called by muse, mutect2, varscan2
- DLGAP2 | c.1480G>T p.G494* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV70102808; called by muse, mutect2, varscan2
- DLGAP4 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.076); catalogued as COSV100211022; called by muse, mutect2, varscan2
- DLGAP4 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs900115980, COSV59421170; called by muse, mutect2, varscan2
- DMP1 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs866017075, COSV99218607; called by muse, mutect2, varscan2
- DMRTB1 | c.748T>A p.L250M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV101008271; called by muse, mutect2, varscan2
- DNAH11 | c.3484A>T p.N1162Y | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100178366; called by muse, mutect2
- DNAH2 | c.1003A>T p.N335Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99318042; called by muse, mutect2, varscan2
- DNAH5 | c.10318G>T p.A3440S | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99447416; called by muse, mutect2
- DNAH9 | c.5152-1G>T p.X1718_splice | Splice Site (SNP) | VAF 12/169 reads (7%) | catalogued as COSV99305064; called by muse, mutect2
- DNAJC27 | c.529-1G>C p.X177_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53095463, COSV53096436; called by muse, mutect2, varscan2
- DNAJC3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV100953306; called by muse, mutect2, varscan2
- DNMT3A | c.2726T>C p.F909S | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53048691, COSV99066220; called by muse, mutect2, varscan2
- DNMT3A | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 48/176 reads (27%) | catalogued as COSV99261172; called by muse, mutect2, varscan2
- DOCK2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99911266; called by muse, mutect2
- DOCK9 | c.256A>G p.R86G (on ENST00000376460 / NM_001366676.2; = p.R87G on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100238580; called by muse, mutect2
- DPP4 | c.1420+2T>A p.X474_splice | Splice Site (SNP) | VAF 20/112 reads (18%) | catalogued as COSV100858770; called by muse, mutect2, varscan2
- DPP6 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.935); catalogued as COSV101341458; called by muse, mutect2, varscan2
- DPP8 | c.1727G>A p.C576Y (on ENST00000341861 / NM_001320875.2; = p.C560Y on NM_017743.6) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1415387200, COSV100202218; called by muse, mutect2, varscan2
- DRD2 | c.1157G>T p.W386L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100669446; called by muse, mutect2, varscan2
- DSE | c.2420A>G p.K807R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100528463, COSV59064783; called by muse, varscan2
- DSP | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101131211, COSV65793314; called by muse, mutect2, varscan2
- DSP | c.2534A>C p.Q845P | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as COSV101131212; called by muse, mutect2, varscan2
- DSP | c.7089C>A p.H2363Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV101131213, COSV65793136; called by muse, mutect2, varscan2
- DSTYK | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100904506; called by muse, mutect2
- DYM | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99492861; called by muse, mutect2, varscan2
- DYNC1I1 | c.313A>C p.T105P | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100267966; called by muse, mutect2, varscan2
- DYSF | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99245646; called by muse, mutect2
- EFCAB3 | c.499A>T p.R167* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100540121; called by muse, mutect2
- EFS | c.395G>T p.R132I | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99391453; called by muse, mutect2, varscan2
- EGF | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.677); catalogued as COSV99490682; called by muse, mutect2, varscan2
- EGFLAM | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100380102; called by muse, mutect2
- EIF4G1 | c.4388G>T p.W1463L (on ENST00000346169 / NM_198241.3; = p.W1268L on NM_004953.5) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100071633; called by muse, mutect2, varscan2
- ELAPOR2 | c.2171G>T p.G724V (on ENST00000450689 / NM_001142749.3; = p.G557V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99788505; called by muse, mutect2
- ELAPOR2 | c.1441G>T p.G481C (on ENST00000450689 / NM_001142749.3; = p.G314C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV99788507; called by muse, mutect2, varscan2
- ELAVL4 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV100836650; called by muse, mutect2, varscan2
- ELAVL4 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs767350030, COSV100836653; called by muse, mutect2, varscan2
- EMB | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs893442296, COSV100296548; called by muse, mutect2, varscan2
- EML5 | c.902A>T p.Q301L | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100715308, COSV61352278; called by muse, varscan2
- EML5 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs756949196, COSV100715312; called by muse, varscan2
- ENC1 | c.1171T>A p.Y391N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187977; called by muse, mutect2, varscan2
- ENPP6 | c.702C>A p.N234K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57067118; called by muse, mutect2, varscan2
- EPGN | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV59741059; called by muse, mutect2, varscan2
- EPHA5 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56660453; called by muse, mutect2, varscan2
- EPHA5 | c.792C>A p.N264K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs1056564404, COSV99897691; called by muse, mutect2
- EPHA8 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1207181815, COSV51272201, COSV99384553; called by muse, mutect2, varscan2
- EPHB1 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV101212914; called by muse, mutect2, varscan2
- EPHB4 | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV62267941, COSV62269321; called by muse, mutect2
- ERCC6 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100875823; called by muse, mutect2, varscan2
- ERICH3 | c.2405G>A p.G802E | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100443878, COSV58616526; called by muse, mutect2
- ERP44 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV99316298; called by muse, mutect2, varscan2
- ERV3-1 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99275389; called by muse, mutect2, varscan2
- EVC2 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100185503; called by muse, mutect2, varscan2
- EVI2A | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.111); catalogued as COSV55986205; called by muse, mutect2, varscan2
- EVX2 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100420624; called by muse, mutect2, varscan2
- EXOC1 | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as COSV100637798; called by muse, mutect2, varscan2
- EXOC1 | c.1074+1G>T p.X358_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100637800; called by muse, mutect2, varscan2
- EYA2 | c.996C>A p.H332Q | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100426638; called by muse, mutect2, varscan2
- F5 | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 56/467 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV100889022; called by muse, mutect2, varscan2
- FADS2 | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs745742269, COSV99608551; called by muse, mutect2, varscan2
- FAM47C | c.1477A>C p.T493P | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100792411; called by muse, mutect2, varscan2
- FAM50A | c.914A>T p.K305M | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50133041, COSV99340967; called by muse, mutect2, varscan2
- FAM71A | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs569094271, COSV54234820; called by muse, mutect2, varscan2
- FAM83F | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100328891; called by muse, mutect2
- FAM91A1 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100593501; called by muse, mutect2
- FAM91A1 | c.1216A>G p.M406V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1185508589, COSV100593503; called by muse, mutect2, varscan2
- FANCM | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99950796; called by muse, mutect2, varscan2
- FAR2 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV51724360; called by muse, mutect2, varscan2
- FAT1 | c.12619A>T p.S4207C | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101499224; called by muse, mutect2, varscan2
- FAT1 | c.11453G>C p.C3818S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV101499226, COSV71674852; called by muse, mutect2, varscan2
- FAT4 | c.3229G>T p.V1077L | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.099); catalogued as COSV101272182; called by muse, mutect2
- FAT4 | c.13219G>C p.A4407P | Missense Mutation (SNP) | VAF 106/539 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100627974; called by muse, mutect2, varscan2
- FBL | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99695243; called by muse, mutect2
- FBLN2 | c.1934G>T p.R645L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99851622; called by muse, mutect2, varscan2
- FBXL4 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV100013980; called by muse, mutect2, varscan2
- FBXO11 | c.737A>T p.K246M (on ENST00000403359 / NM_001190274.2; = p.K162M on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); catalogued as COSV100319269; called by muse, mutect2, varscan2
- FCRL3 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV100943019; called by muse, mutect2, varscan2
- FER1L6 | c.5121C>A p.F1707L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67551521; called by muse, mutect2
- FGA | c.2008G>T p.G670* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100120250; called by muse, mutect2, varscan2
- FGGY | c.1317A>G p.I439M | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100364188; called by muse, mutect2, varscan2
- FHOD3 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV57185331; called by muse, mutect2, varscan2
- FHOD3 | c.2113C>A p.Q705K (on ENST00000359247 / NM_001281739.3; = p.Q722K on NM_025135.5) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as rs188731619; called by muse, mutect2, varscan2
- FIGN | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100292049; called by muse, mutect2
- FLG | c.11364C>A p.H3788Q | Missense Mutation (SNP) | VAF 165/887 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as COSV100911334; called by muse, mutect2, varscan2
- FLG | c.3329G>T p.R1110M | Missense Mutation (SNP) | VAF 50/755 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV100911337; called by muse, mutect2
- FLG2 | c.7030T>A p.W2344R | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV101165741; called by muse, mutect2
- FLNC | c.5329C>A p.P1777T | Missense Mutation (SNP) | VAF 47/599 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100367836; called by muse, mutect2
- FLRT2 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100420191; called by muse, mutect2, varscan2
- FMN2 | c.2951C>A p.A984E | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.071); catalogued as COSV100144200, COSV60420884; called by muse, varscan2
- FMN2 | c.3397C>A p.P1133T | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as COSV100144171, COSV60450071; called by muse, varscan2
- FMN2 | c.3457C>A p.P1153T | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60416918; called by muse, varscan2
- FMN2 | c.3458C>T p.P1153L | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.979); catalogued as rs775610456, COSV100144203; called by muse, varscan2
- FOXN2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs763819495, COSV100489063; called by muse, mutect2, varscan2
- FOXN3 | c.1400G>T p.R467L (on ENST00000261302; = p.R445L on NM_005197.4) | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99726089; called by muse, mutect2, varscan2
- FOXRED2 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99340782; called by muse, mutect2, varscan2
- FRAS1 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99350079; called by muse, mutect2, varscan2
- FRMD4A | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV99198456; called by muse, mutect2, varscan2
- FRMD6 | c.1612A>G p.T538A (on ENST00000344768 / NM_001267046.2; = p.T530A on NM_152330.4) | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as rs1159095228, COSV100655637; called by muse, mutect2, varscan2
- FSCB | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100469110, COSV100469762; called by muse, mutect2, varscan2
- FSHR | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1467838512, COSV58629723; called by muse, mutect2, varscan2
- FXYD5 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100732611; called by muse, mutect2, varscan2
- GAB1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749186578, COSV53756341; called by muse, mutect2, varscan2
- GABRA1 | c.467A>T p.Y156F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV99195786; called by muse, mutect2, varscan2
- GABRA6 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99194193; called by muse, mutect2, varscan2
- GABRA6 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99194195; called by muse, varscan2
- GABRG3 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); catalogued as COSV100406060; called by muse, mutect2, varscan2
- GAK | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100033366; called by muse, mutect2
- GAL3ST4 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs763411487, COSV52784526; called by muse, mutect2, varscan2
- GALNT14 | c.201G>C p.W67C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100204376; called by muse, mutect2, varscan2
- GARNL3 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.51); catalogued as COSV100150073; called by muse, mutect2, varscan2
- GATA3 | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100650902; called by muse, mutect2, varscan2
- GBP4 | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100864344; called by muse, mutect2, varscan2
- GBP7 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99642987; called by muse, mutect2, varscan2
- GBX1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV52546994, COSV99880826; called by muse, mutect2, varscan2
- GCLC | c.14C>A p.P5Q (on ENST00000643939; = p.P9Q on NM_001498.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427252491, COSV99988464; called by muse, varscan2
- GCNT4 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); catalogued as COSV100466331; called by muse, mutect2, varscan2
- GDA | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.255); catalogued as COSV99429020; called by muse, mutect2, varscan2
- GDF9 | c.604C>A p.Q202K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99737239; called by muse, mutect2, varscan2
- GFRA1 | c.797A>T p.N266I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100815608; called by muse, mutect2, varscan2
- GIP | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV100656928; called by muse, mutect2, varscan2
- GJA8 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150041151, COSV53790052; called by muse, mutect2, varscan2
- GJC1 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV100395146; called by muse, mutect2
- GLCCI1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99780236; called by muse, mutect2, varscan2
- GLI1 | c.1594C>A p.R532S | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99953906; called by muse, mutect2, varscan2
- GLI2 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100082775, COSV58046525; called by muse, mutect2, varscan2
- GLP1R | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100952522; called by muse, mutect2, varscan2
- GLP1R | c.851G>A p.W284* | Nonsense Mutation (SNP) | VAF 24/218 reads (11%) | catalogued as COSV100952523; called by muse, mutect2, varscan2
- GLP1R | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952525, COSV64716774; called by muse, mutect2, varscan2
- GOPC | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99270840; called by muse, mutect2, varscan2
- GPA33 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as rs200617447, COSV63301245; called by muse, mutect2, varscan2
- GPAM | c.960G>T p.R320S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100788140; called by muse, mutect2, varscan2
- GPC6 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100988300; called by muse, mutect2, varscan2
- GPR1 | c.600G>T p.L200F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.185); catalogued as rs1359358234, COSV101329839, COSV101329881; called by muse, mutect2, varscan2
- GPR149 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101078268; called by muse, mutect2, varscan2
- GPR149 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV101078269; called by muse, mutect2, varscan2
- GPRASP1 | c.3463G>C p.E1155Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100850955; called by muse, mutect2, varscan2
- GPRC5B | c.1193C>A p.T398K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100244660; called by muse, mutect2, varscan2
- GPX6 | c.511T>G p.W171G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100724793; called by muse, mutect2, varscan2
- GRAMD1A | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.737); catalogued as COSV100526057; called by muse, mutect2, varscan2
- GRID2 | c.2476C>A p.L826M | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99939131; called by muse, mutect2, varscan2
- GRIK3 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | catalogued as COSV100901676; called by muse, mutect2, varscan2
- GRIN2A | c.1825T>C p.W609R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100409154; called by muse, mutect2, varscan2
- GRM3 | c.2573C>A p.A858E | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV100862345; called by muse, mutect2, varscan2
- GRM8 | c.2705G>T p.S902I | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs10225567, COSV100281714; called by muse, mutect2, varscan2
- GRSF1 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.107); catalogued as rs1323742123, COSV99635610; called by muse, mutect2
- GRXCR1 | c.45A>T p.K15N | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV101295644; called by muse, mutect2
- GSK3B | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV99954447; called by muse, mutect2, varscan2
- GSN | c.2236G>T p.V746L | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100375986; called by muse, mutect2, varscan2
- GSX2 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100482530; called by muse, mutect2, varscan2
- H1-2 | c.533A>T p.K178M | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100642269; called by muse, mutect2, varscan2
- H2AC8 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV55127037, COSV55127859, COSV99773137; called by muse, mutect2, varscan2
- H2BC7 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 52/303 reads (17%) | catalogued as COSV100587144, COSV61911775; called by muse, mutect2, varscan2
- HAVCR1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV100208102; called by muse, mutect2, varscan2
- HBS1L | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 11/350 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV100122046; called by muse, mutect2
- HCN1 | c.2513G>C p.R838P | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100299477; called by muse, mutect2, varscan2
- HCRTR2 | c.956C>A p.P319Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904256; called by muse, mutect2, varscan2
- HDX | c.1929T>A p.D643E | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99946985; called by muse, mutect2
- HECTD4 | c.1912G>T p.G638* | Nonsense Mutation (SNP) | VAF 35/244 reads (14%) | catalogued as COSV100295923; called by muse, mutect2, varscan2
- HEG1 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100230299; called by muse, mutect2
- HELB | c.1876C>A p.P626T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99921712; called by muse, mutect2, varscan2
- HEPACAM | c.884C>G p.T295S | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100005586; called by muse, mutect2, varscan2
- HERC2 | c.7581G>T p.E2527D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99872172; called by muse, mutect2, varscan2
- HGF | c.1570A>T p.I524L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as COSV99736272; called by muse, mutect2, varscan2
- HIP1 | c.1761G>T p.R587S | Missense Mutation (SNP) | VAF 95/469 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100417250; called by muse, mutect2, varscan2
- HIP1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374151055, COSV100416783; called by muse, mutect2, varscan2
- HIVEP2 | c.4157G>T p.G1386V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99171757; called by muse, mutect2, varscan2
- HIVEP3 | c.5167C>A p.Q1723K | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99912025; called by muse, mutect2, varscan2
- HLCS | c.855G>T p.L285F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV100358044; called by muse, mutect2
- HMCN1 | c.9570G>T p.K3190N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); catalogued as COSV99626655; called by muse, mutect2, varscan2
- HNRNPA0 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100152886; called by muse, mutect2, varscan2
- HNRNPA1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV99267493; called by muse, mutect2, varscan2
- HOMEZ | c.1472G>T p.S491I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100664073; called by muse, mutect2, varscan2
- HOXB1 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV99495408; called by muse, mutect2, varscan2
- HOXB3 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100290599; called by muse, mutect2, varscan2
- HOXC13 | c.768C>A p.S256R | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV99673329; called by muse, mutect2, varscan2
- HOXD11 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99983220; called by muse, mutect2
- HSD17B12 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV99550535; called by muse, mutect2, varscan2
- HSD3B7 | c.798G>T p.R266S | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV99288009; called by muse, mutect2, varscan2
- HTR3B | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99491869; called by muse, mutect2
- HTR5A | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99839561; called by muse, mutect2
- HUWE1 | c.13015C>A p.H4339N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53340328, COSV99471361, COSV99473277; called by muse, mutect2, varscan2
- HUWE1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99471362; called by muse, mutect2, varscan2
- IBSP | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99883453; called by muse, mutect2, varscan2
- IFI44 | c.1002G>T p.L334F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV100877293; called by muse, mutect2, varscan2
- IGF2BP1 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762860271, COSV99288450; called by muse, mutect2, varscan2
- IGF2BP2 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100648966; called by muse, mutect2, varscan2
- IGLV8-61 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV101135037, COSV66503205; called by muse, mutect2, varscan2
- IGSF22 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100079418; called by muse, mutect2, varscan2
- IKZF1 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100498199, COSV100498439; called by muse, mutect2, varscan2
- IL18RAP | c.773A>C p.E258A | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV99961857; called by muse, varscan2
- IL36G | c.55+1G>A p.X19_splice | Splice Site (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99381125; called by muse, mutect2, varscan2
- ILDR2 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99613542; called by muse, mutect2, varscan2
- INPP1 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100487153; called by muse, mutect2, varscan2
- INPP5J | c.2110C>A p.Q704K (on ENST00000331075 / NM_001284285.2; = p.Q336K on NM_001002837.2) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100459310, COSV58511865; called by muse, mutect2, varscan2
- INSYN1 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV101138717, COSV65837299; called by muse, mutect2, varscan2
- INTU | c.901A>T p.S301C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV99611528; called by muse, mutect2, varscan2
- IPO7 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.315); catalogued as rs1419485900, COSV101121805; called by muse, mutect2, varscan2
- IQCE | c.130A>T p.K44* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100383303; called by muse, mutect2, varscan2
- IRAK3 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV54166513; called by muse, mutect2, varscan2
- ITGA2 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670512; called by muse, mutect2, varscan2
- ITGA8 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV65224878; called by muse, varscan2
- ITGA8 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554785312, COSV100959058; called by muse, varscan2
- ITGAD | c.1721C>G p.S574C | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV101210407; called by muse, mutect2, varscan2
- ITGAV | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV53718543, COSV99654582; called by muse, mutect2, varscan2
- ITGB3 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV101457565; called by muse, mutect2, varscan2
- ITIH2 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100623240, COSV64435503; called by muse, mutect2, varscan2
- ITSN1 | c.4404G>C p.K1468N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV101181560, COSV101182222; called by muse, mutect2, varscan2
- ITSN2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100743060; called by muse, mutect2, varscan2
- KALRN | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as COSV99563153; called by muse, mutect2, varscan2
- KALRN | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.927); catalogued as COSV99563155; called by muse, mutect2, varscan2
- KARS1 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100093914; called by muse, mutect2
- KATNIP | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | catalogued as COSV99850495; called by muse, mutect2, varscan2
- KCNA3 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV100871227; called by muse, mutect2
- KCNB1 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 21/395 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV100870424, COSV65569506; called by muse, mutect2
- KCNC2 | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100128507; called by muse, mutect2
- KCNH1 | c.1796C>A p.T599K (on ENST00000271751 / NM_172362.3; = p.T572K on NM_002238.4) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55094082, COSV99658274; called by muse, mutect2, varscan2
- KCNH2 | c.2297G>T p.G766V | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100059596, COSV51220822; called by muse, mutect2, varscan2
- KCNH2 | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100059601; called by muse, mutect2, varscan2
- KCNH5 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100525940; called by muse, mutect2, varscan2
- KCNH6 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV100121305, COSV59002760; called by muse, mutect2, varscan2
- KCNJ6 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99899516; called by muse, mutect2
- KCNMA1 | c.3077T>A p.L1026Q (on ENST00000286628 / NM_001161352.2; = p.L968Q on NM_002247.4) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99696136; called by muse, mutect2, varscan2
- KCNT1 | c.1390C>T p.P464S (on ENST00000488444; = p.P483S on NM_020822.3) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV99705370; called by muse, mutect2, varscan2
- KCNU1 | c.2214G>T p.L738F | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101299073; called by muse, mutect2, varscan2
- KCTD16 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV72579656, COSV72580338; called by muse, mutect2, varscan2
- KDM6A | c.3587A>G p.N1196S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.797); catalogued as rs374939363, COSV100938022; called by muse, varscan2
- KDR | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV55757267; called by muse, mutect2
- KHDRBS3 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV100878487, COSV100878535; called by muse, mutect2, varscan2
- KIAA1109 | c.4544G>T p.W1515L | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99151078; called by muse, mutect2, varscan2
- KIAA1109 | c.6113G>T p.G2038V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151080; called by muse, mutect2
- KIAA1755 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99641738; called by muse, mutect2, varscan2
- KIAA2026 | c.1662G>T p.L554F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs557312089, COSV101198943; called by muse, mutect2, varscan2
- KIF13B | c.4318G>C p.D1440H | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV101342253; called by muse, mutect2, varscan2
- KIF14 | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100950739; called by muse, mutect2, varscan2
- KIF17 | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99928796; called by muse, mutect2, varscan2
- KIF17 | c.671-1G>T p.X224_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99928800; called by muse, mutect2, varscan2
- KIF1A | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 43/237 reads (18%) | catalogued as COSV100240346; called by muse, mutect2, varscan2
- KIF21B | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100144191; called by muse, mutect2, varscan2
- KLHDC8A | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100903805; called by muse, mutect2, varscan2
- KLHL23 | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV99775654; called by muse, mutect2, varscan2
- KLHL38 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV58086042; called by muse, mutect2, varscan2
- KLHL4 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100909347; called by muse, mutect2, varscan2
- KMT2C | c.4540G>T p.E1514* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100069621; called by muse, mutect2
- KMT2C | c.2678A>T p.K893M | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765468622, COSV100069623; called by muse, mutect2, varscan2
- KNG1 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV99405358; called by muse, mutect2, varscan2
- KRR1 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99875597; called by muse, mutect2, varscan2
- KRT12 | c.1151T>A p.L384Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99288863; called by muse, mutect2
- KRT34 | c.202T>A p.C68S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV101222589; called by muse, mutect2
- KRT75 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52871208, COSV52871301; called by muse, mutect2, varscan2
- KRTAP10-1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100552560; called by muse, mutect2, varscan2
- KRTAP10-5 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 72/574 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100552562; called by muse, varscan2
- KRTAP4-1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893456; called by muse, mutect2, varscan2
- KRTAP4-1 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100893457; called by muse, mutect2, varscan2
- KRTAP4-5 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100576776; called by muse, mutect2, varscan2
- KRTAP9-2 | c.80C>A p.T27N | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs1345606117, COSV100893152; called by muse, varscan2
- LAD1 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV100943813; called by muse, mutect2, varscan2
- LAMA2 | c.2975C>A p.T992K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV101370274; called by muse, mutect2, varscan2
- LAMA3 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); catalogued as COSV100556100; called by muse, varscan2
- LAMA4 | c.4955C>T p.S1652L (on ENST00000230538 / NM_001105206.3; = p.S1645L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100037979; called by muse, varscan2
- LAMB1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99740321; called by muse, mutect2
- LAMTOR3 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99896018; called by muse, mutect2
- LARGE1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as COSV100504999; called by muse, mutect2, varscan2
- LCE1C | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100908428, COSV64218247; called by muse, mutect2
- LCLAT1 | c.629A>T p.N210I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.11); catalogued as COSV100092320; called by muse, mutect2, varscan2
- LGR5 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1412029287, COSV99877749; called by muse, mutect2, varscan2
- LGR5 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV99877751; called by muse, mutect2, varscan2
- LHX2 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV101010037; called by mutect2, varscan2
- LHX6 | c.372C>A p.F124L (on ENST00000373755 / NM_001242334.2; = p.F153L on NM_014368.5) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as COSV100493301; called by mutect2, varscan2
- LILRA2 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as COSV99253059; called by muse, mutect2, varscan2
- LILRB1 | c.1768C>A p.Q590K (on ENST00000427581; = p.Q540K on NM_006669.6) | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV100207111; called by muse, varscan2
- LIMS2 | c.227G>T p.C76F (on ENST00000355119 / NM_001161403.3; = p.C100F on NM_017980.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99760486; called by muse, mutect2
- LIMS2 | c.226T>C p.C76R (on ENST00000355119 / NM_001161403.3; = p.C100R on NM_017980.4) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1215030183, COSV99760488; called by muse, mutect2
- LINGO2 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430397; called by muse, mutect2, varscan2
- LIPI | c.1055C>G p.T352R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100753571; called by muse, mutect2, varscan2
- LIPK | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.856); catalogued as COSV68201601; called by muse, mutect2, varscan2
- LPO | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99228602; called by muse, mutect2, varscan2
- LPP | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV100446619; called by muse, mutect2, varscan2
- LRBA | c.8349+1G>T p.X2783_splice | Splice Site (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100841226; called by muse, mutect2, varscan2
- LRFN2 | c.307C>A p.R103S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100599328; called by muse, varscan2
- LRP12 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99407462; called by muse, mutect2, varscan2
- LRP6 | c.1460C>A p.T487N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV99742871; called by muse, mutect2
- LRRC25 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs768001126, COSV100170475; called by muse, mutect2, varscan2
- LRRC4C | c.889C>A p.H297N | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV53436953; called by muse, mutect2, varscan2
- LRRC7 | c.2429C>G p.S810W (on ENST00000651989 / NM_001370785.2; = p.S777W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99225608; called by muse, mutect2, varscan2
- LRRIQ3 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV63048403; called by muse, mutect2, varscan2
- LSMEM2 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100269380; called by muse, mutect2, varscan2
- LTBP1 | c.1307G>T p.G436V (on ENST00000404816 / NM_206943.4; = p.G110V on NM_000627.4) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100616739; called by muse, mutect2
- LYST | c.5980A>T p.K1994* | Nonsense Mutation (SNP) | VAF 53/348 reads (15%) | catalogued as COSV101088823; called by muse, mutect2, varscan2
- LYVE1 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV99811000; called by muse, mutect2, varscan2
- MAGI2 | c.2465G>C p.G822A | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100833869; called by muse, mutect2, varscan2
- MAN2A1 | c.2396C>T p.T799I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV99810730; called by muse, mutect2, varscan2
- MAP3K21 | c.2228A>T p.H743L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100786088; called by muse, mutect2, varscan2
- MAP3K3 | c.1598G>T p.W533L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99368486; called by muse, varscan2
- MARK1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100857135; called by muse, mutect2, varscan2
- MB21D2 | c.1044G>T p.L348F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101165067; called by muse, mutect2, varscan2
- MBD1 | c.716A>T p.H239L | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV99495887; called by muse, mutect2
- MBLAC2 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100353078; called by muse, mutect2, varscan2
- MCM3AP | c.1675G>T p.V559L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV99386653; called by muse, varscan2
- MDGA1 | c.2717T>C p.I906T | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99776623; called by muse, mutect2, varscan2
- MEX3B | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100313945; called by muse, mutect2, varscan2
- MFRP | c.437G>T p.G146V (on ENST00000449574; = p.G522V on NM_031433.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100264762; called by mutect2, varscan2
- MFSD2A | c.1501C>T p.L501F (on ENST00000372809 / NM_001136493.3; = p.L488F on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100861636; called by muse, mutect2, varscan2
- MFSD2B | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV100601019; called by muse, mutect2, varscan2
- MGAT4C | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59830747; called by muse, mutect2, varscan2
- MIA2 | c.2369C>G p.S790* | Nonsense Mutation (SNP) | VAF 41/221 reads (19%) | catalogued as COSV99697470; called by muse, mutect2, varscan2
- MIB1 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99838551; called by muse, mutect2, varscan2
- MIB2 | c.2431G>C p.A811P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100598804; called by muse, mutect2
- MIER2 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99316184; called by muse, mutect2
- MINDY4 | c.1074-2A>T p.X358_splice | Splice Site (SNP) | VAF 20/295 reads (7%) | catalogued as COSV99518417; called by muse, mutect2
- MIOS | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100402646; called by muse, mutect2
- MKS1 | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99836370; called by muse, mutect2, varscan2
- MLKL | c.1333A>T p.I445F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100087257; called by muse, mutect2, varscan2
- MMEL1 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56520346, COSV99983501; called by muse, mutect2, varscan2
- MMRN1 | c.2861C>A p.P954Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99306820; called by muse, mutect2
- MON1B | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99941627; called by muse, mutect2, varscan2
- MOSPD3 | c.512-1G>T p.X171_splice | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as COSV99774907; called by muse, mutect2, varscan2
- MPV17 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.445); catalogued as COSV51989807, COSV99272442; called by muse, mutect2, varscan2
- MRE11 | c.2083G>T p.D695Y (on ENST00000323929 / NM_005591.4; = p.D667Y on NM_005590.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100119528; called by muse, mutect2, varscan2
- MROH2B | c.2932G>T p.E978* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as COSV101270609, COSV68181699; called by muse, mutect2
- MS4A14 | c.1810C>A p.Q604K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV55732884; called by muse, mutect2
- MS4A3 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV99614632; called by muse, mutect2, varscan2
- MS4A7 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV100279434; called by muse, mutect2
- MSR1 | c.104-1G>C p.X35_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100026868, COSV50513363; called by muse, varscan2
- MSRB3 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100377658; called by muse, mutect2, varscan2
- MTCL1 | c.4819G>T p.A1607S (on ENST00000306329 / NM_001378206.1; = p.A1288S on NM_015210.4) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100094002; called by muse, mutect2, varscan2
- MTHFR | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV64701502; called by muse, mutect2, varscan2
- MTMR4 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV100050908; called by muse, mutect2, varscan2
- MUC16 | c.40889C>G p.A13630G | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.937); catalogued as COSV101109754; called by muse, mutect2, varscan2
- MUC16 | c.12088A>G p.T4030A | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.058); catalogued as rs763290166, COSV101199134; called by muse, mutect2, varscan2
- MUC5AC | c.15689C>A p.P5230H | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100611382; called by muse, mutect2
- MUC5B | c.10534C>A p.P3512T | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV101500191; called by muse, mutect2, varscan2
- MUC6 | c.4001C>A p.P1334Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV101424484; called by muse, mutect2, varscan2
- MXRA5 | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99476291; called by muse, mutect2, varscan2
- MYBPC1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100637857; called by muse, mutect2
- MYEF2 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981374; called by muse, mutect2, varscan2
- MYH3 | c.3830A>T p.Q1277L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99877980; called by muse, mutect2, varscan2
- MYH7 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV100805883, COSV62518511; called by muse, mutect2, varscan2
- MYH8 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV101238341; called by muse, mutect2, varscan2
- MYO16 | c.2813A>T p.E938V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99193749; called by muse, mutect2, varscan2
- MYOC | c.935C>G p.P312R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231405; called by muse, mutect2, varscan2
- MYOM2 | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs375181421; called by muse, mutect2, varscan2
- MYOM2 | c.3007C>A p.R1003S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV100037148; called by muse, mutect2
- MYOM3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100292711; called by muse, mutect2
- NAALADL2 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV101458171, COSV70296688; called by muse, varscan2
- NACA | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100771196; called by muse, mutect2, varscan2
- NALCN | c.4540C>T p.H1514Y | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV99213975; called by muse, mutect2, varscan2
- NALCN | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51932997, COSV99213977; called by muse, mutect2, varscan2
- NAP1L4 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101000674; called by muse, mutect2, varscan2
- NAV2 | c.1195G>T p.V399F (on ENST00000396087 / NM_001244963.2; = p.V376F on NM_145117.5) | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs780761494, COSV100585306; called by muse, mutect2, varscan2
- NBAS | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99868375; called by muse, mutect2, varscan2
- NCAPG | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV99265818; called by muse, mutect2, varscan2
- NCAPG2 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99316735; called by muse, mutect2, varscan2
- NCOA5 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as rs781272346, COSV99275391; called by muse, mutect2, varscan2
- NDC1 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99323459; called by muse, mutect2, varscan2
- NDE1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.841); catalogued as COSV100706868; called by muse, mutect2, varscan2
- NDST4 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99995993; called by muse, mutect2
- NDUFA8 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101056778; called by muse, mutect2, varscan2
- NDUFB1 | c.81A>T p.L27F | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV100102687; called by muse, mutect2, varscan2
- NEB | c.10672G>C p.D3558H | Missense Mutation (SNP) | VAF 67/478 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99418537; called by muse, mutect2, varscan2
- NEB | c.4182G>T p.K1394N | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99418544; called by muse, mutect2
- NEBL | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101012278; called by muse, mutect2, varscan2
- NEGR1 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.823); catalogued as COSV100162202; called by muse, mutect2, varscan2
- NEK10 | c.2972G>T p.S991I | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV99834949; called by muse, mutect2
- NETO1 | c.1365G>T p.L455F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.991); catalogued as COSV55016993; called by muse, mutect2, varscan2
- NF1 | c.2950G>T p.G984W | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100646448; called by muse, mutect2, varscan2
- NFASC | c.707C>A p.T236N (on ENST00000339876 / NM_001378329.1; = p.A247D on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV100363328; called by muse, mutect2, varscan2
- NFKBIZ | c.1980G>C p.Q660H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100396981; called by muse, mutect2, varscan2
- NID2 | c.2533A>T p.I845F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV99356214; called by muse, mutect2, varscan2
- NID2 | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV99356216; called by muse, mutect2, varscan2
- NLGN1 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100849033; called by muse, mutect2, varscan2
- NOX4 | c.1217+1G>T p.X406_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99630106; called by muse, mutect2, varscan2
- NPAS4 | c.1302T>G p.C434W | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as rs1325758577, COSV100214896; called by muse, mutect2, varscan2
- NPFFR2 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as COSV100440502; called by muse, mutect2, varscan2
- NPNT | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1560540851, COSV99974914; called by muse, mutect2, varscan2
- NPTXR | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs757970245, COSV100285407; called by muse, mutect2, varscan2
- NQO2 | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100583169; called by muse, mutect2, varscan2
- NR2F1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100504606; called by muse, mutect2, varscan2
- NRCAM | c.2095G>A p.E699K (on ENST00000379028 / NM_001371124.1; = p.E683K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100694509; called by muse, mutect2, varscan2
- NRP2 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 86/707 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313539710, COSV55930324; called by muse, varscan2
- NRP2 | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 136/886 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV99783871; called by muse, varscan2
- NRXN3 | c.1970T>A p.V657E (on ENST00000335750 / NM_001330195.2; = p.V284E on NM_004796.6) | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV100202400; called by muse, mutect2, varscan2
- NSD1 | c.5681G>T p.R1894L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100728661; called by muse, mutect2, varscan2
- NUBPL | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99809298; called by muse, mutect2, varscan2
- NUP188 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV101001272; called by muse, mutect2
- NUP205 | c.4459G>A p.D1487N | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV99606703; called by muse, mutect2, varscan2
- NUP210 | c.3389G>T p.G1130V | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595891; called by muse, mutect2, varscan2
- NUP214 | c.2104G>T p.V702L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV63912407; called by muse, mutect2, varscan2
- NUTM2G | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100672677; called by muse, mutect2, varscan2
- NWD1 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV100342163; called by muse, mutect2, varscan2
- NYAP1 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55718553; called by muse, mutect2, varscan2
- OAS2 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100660054, COSV60802611; called by muse, mutect2, varscan2
- OPRPN | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); catalogued as COSV68192819; called by muse, mutect2, varscan2
- OR13J1 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100940776; called by muse, mutect2, varscan2
- OR1C1 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.309); catalogued as COSV101376206, COSV68715735; called by muse, mutect2
- OR2AG2 | c.764C>G p.A255G | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV100643098; called by muse, mutect2, varscan2
- OR2D3 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100505019; called by muse, varscan2
- OR2F2 | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68833176; called by muse, mutect2, varscan2
- OR2L13 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs202188433, COSV63549839; called by muse, mutect2, varscan2
- OR2M5 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100822785, COSV100822882, COSV63546894; called by muse, mutect2, varscan2
- OR2T12 | c.17C>A p.T6N | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100527658; called by muse, mutect2, varscan2
- OR2T27 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV100788176; called by muse, mutect2, varscan2
- OR2T34 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170316; called by muse, mutect2, varscan2
- OR2V2 | c.785G>T p.R262M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60314853; called by muse, mutect2, varscan2
- OR4A47 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs1467219301, COSV101487058; called by muse, mutect2, varscan2
- OR4C11 | c.563T>A p.M188K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.75); catalogued as COSV100155284; called by muse, mutect2, varscan2
- OR4M1 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs373106058; called by muse, mutect2, varscan2
- OR52E2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs751039508, COSV100384743; called by muse, mutect2, varscan2
- OR56A1 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100360431; called by muse, mutect2, varscan2
- OR5I1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV56886325; called by muse, mutect2, varscan2
- OR5K2 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV101415959; called by muse, mutect2, varscan2
- OR5M1 | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101591547; called by muse, mutect2, varscan2
- OR5P2 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100271261; called by muse, mutect2, varscan2
- OR6C3 | c.367A>T p.I123F | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV101110328; called by muse, mutect2, varscan2
- OR6N2 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV104411267, COSV59411832; called by muse, mutect2, varscan2
- OTOGL | c.1955C>A p.T652N (on ENST00000547103; = p.T643N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV101509102; called by muse, mutect2, varscan2
- OVCH2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101491874; called by muse, mutect2
- OVCH2 | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV101491875; called by muse, mutect2
- PAK5 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 36/214 reads (17%) | catalogued as COSV62023013, COSV62026441; called by muse, mutect2, varscan2
- PALD1 | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99698129; called by muse, mutect2, varscan2
- PALLD | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99824308; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.876G>T p.E292D (on ENST00000374531 / NM_001037293.2; = p.E324D on NM_053016.6) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.069); catalogued as COSV100092860; called by muse, mutect2, varscan2
- PAPOLG | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99474566; called by muse, mutect2, varscan2
- PAPPA2 | c.42G>T p.L14F | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100866688; called by muse, mutect2
- PAPSS2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753480; called by muse, mutect2
- PAPSS2 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV100753481; called by muse, mutect2, varscan2
- PARD3B | c.3181-1G>T p.X1061_splice (on ENST00000406610 / NM_001302769.2; = p.X992_splice on NM_057177.7) | Splice Site (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100592876; called by muse, mutect2, varscan2
- PCARE | c.3476C>A p.P1159Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100527442; called by muse, mutect2, varscan2
- PCARE | c.2992A>G p.R998G | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100527443; called by muse, mutect2
- PCDH10 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99993265; called by muse, mutect2, varscan2
- PCDH11X | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs749355536, COSV100010356, COSV53469498; called by muse, mutect2, varscan2
- PCDH11Y | c.763G>C p.D255H (on ENST00000400457 / NM_032973.2; = p.D244H on NM_032971.3) | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291041; called by muse, mutect2, varscan2
- PCDH15 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100218076; called by muse, mutect2, varscan2
- PCDH17 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759765507, COSV64971698; called by muse, mutect2, varscan2
- PCDH8 | c.2839+2T>A p.X947_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100131386; called by muse, mutect2, varscan2
- PCDHA4 | c.1370A>T p.Q457L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100793272; called by muse, mutect2, varscan2
- PCDHB12 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53401205, COSV99507167; called by muse, mutect2, varscan2
- PCDHB13 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV99507033; called by muse, mutect2, varscan2
- PCDHB8 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99176505; called by muse, mutect2, varscan2
- PCDHGA2 | c.1292C>A p.S431Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV99534332; called by muse, mutect2, varscan2
- PCLO | c.4178A>G p.K1393R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV100429853; called by muse, mutect2
- PCMTD1 | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs1224098956, COSV100859613; called by muse, mutect2, varscan2
- PCOLCE2 | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99930514; called by muse, mutect2, varscan2
- PCYT2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.889); catalogued as COSV100325937; called by muse, mutect2, varscan2
- PDCD1 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV100545348; called by muse, mutect2, varscan2
- PDE10A | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV100604883; called by muse, mutect2, varscan2
- PDE10A | c.2023C>A p.L675I | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100604885, COSV63104415; called by muse, mutect2, varscan2
- PDE11A | c.2221G>T p.A741S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV99611426; called by muse, mutect2, varscan2
- PDE1B | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1472903745, COSV99226314; called by muse, mutect2, varscan2
- PDE8B | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.206); catalogued as COSV99366495; called by muse, mutect2, varscan2
- PDHA2 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV99756689; called by muse, mutect2, varscan2
- PDZD8 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as rs755666725, COSV100559695; called by muse, mutect2
- PDZRN3 | c.1949T>A p.L650Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99728603; called by muse, mutect2
- PDZRN4 | c.1962C>A p.C654* (on ENST00000402685 / NM_001164595.2; = p.C396* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | catalogued as COSV100114050; called by muse, mutect2, varscan2
- PEG3 | c.2665C>A p.R889S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55634973, COSV99688124; called by muse, mutect2, varscan2
- PER1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs769946260, COSV100424324; called by muse, mutect2, varscan2
- PES1 | c.160G>T p.V54F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100073059; called by muse, mutect2, varscan2
- PEX5L | c.534C>A p.D178E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.007); catalogued as COSV99828320; called by muse, mutect2, varscan2
- PGA5 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs774778577, COSV100409282; called by muse, mutect2, varscan2
- PGLYRP4 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100668355; called by muse, mutect2, varscan2
- PGS1 | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV99428142; called by muse, mutect2, varscan2
- PHEX | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101039530; called by muse, mutect2, varscan2
- PHF2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100823085; called by muse, mutect2, varscan2
- PHTF1 | c.1666A>G p.K556E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100760052; called by muse, mutect2, varscan2
- PIEZO2 | c.7979C>A p.P2660Q | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554774; called by muse, mutect2
- PIP4K2C | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV100723881; called by muse, mutect2, varscan2
- PIWIL2 | c.2785C>A p.H929N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100769309; called by muse, mutect2, varscan2
- PKD2 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV99417080; called by muse, mutect2, varscan2
- PKDREJ | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.614); catalogued as COSV99478634; called by muse, mutect2
- PKHD1L1 | c.8045G>T p.G2682V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101005807, COSV65737482; called by muse, mutect2, varscan2
- PKLR | c.1076G>C p.R359P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM950951, COSV100712852, COSV61361902; called by muse, mutect2, varscan2
- PLA2G4A | c.1860C>G p.C620W | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100820488; called by muse, mutect2, varscan2
- PLCD1 | c.1481A>T p.D494V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99378646, COSV99379313; called by muse, mutect2, varscan2
- PLCE1 | c.4337G>A p.G1446E | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99593744, COSV99594263; called by muse, mutect2
- PLCL1 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs751237081, COSV101406853; called by muse, mutect2, varscan2
- PLCL2 | c.2743A>T p.T915S (on ENST00000615277 / NM_001144382.2; = p.T789S on NM_015184.5) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101196626; called by muse, mutect2
- PLD1 | c.1234G>C p.G412R | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100577891; called by muse, mutect2, varscan2
- PLEKHA4 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99612295; called by muse, mutect2, varscan2
- PLEKHG3 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV99906432; called by muse, mutect2, varscan2
- PLEKHG5 | c.139G>T p.D47Y (on ENST00000400915 / NM_001042663.3; = p.D10Y on NM_020631.6) | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750665205, COSV61703145, COSV61703694; called by muse, mutect2, varscan2
- PLEKHH1 | c.2128G>T p.V710F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV100232889, COSV61283603; called by mutect2, varscan2
- PLG | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99804481; called by muse, mutect2, varscan2
- PLOD3 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777920; called by muse, mutect2, varscan2
- PLPP4 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100956207, COSV100956270; called by muse, mutect2, varscan2
- PLPPR4 | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV100926745; called by muse, mutect2, varscan2
- PLPPR5 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs189031781, COSV99587130; called by muse, mutect2, varscan2
- PLSCR1 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678338; called by muse, mutect2, varscan2
- PLXNA2 | c.3652G>T p.G1218W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374725426, COSV100885286; called by muse, mutect2, varscan2
- PLXNA3 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.988); catalogued as rs1437647251, COSV100859871; called by muse, mutect2, varscan2
- PLXNA4 | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100323415; called by muse, mutect2, varscan2
- PML | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV99166832; called by muse, mutect2, varscan2
- PMS2 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV56223149, COSV99764061; called by muse, mutect2, varscan2
- PMS2 | c.1438G>T p.G480* | Nonsense Mutation (SNP) | VAF 29/181 reads (16%) | catalogued as COSV56224142; called by muse, mutect2, varscan2
- PODN | c.725G>T p.R242M (on ENST00000395871; = p.R194M on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100439442; called by muse, mutect2, varscan2
- PODXL2 | c.1110G>T p.R370S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100686248; called by muse, mutect2, varscan2
- POLE | c.2681G>T p.G894V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100265877; called by muse, mutect2, varscan2
- POLL | c.986G>T p.S329I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100150153; called by muse, mutect2, varscan2
- POLQ | c.7090G>T p.A2364S | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99951904; called by muse, mutect2, varscan2
838 further variants in this file (442 protein-altering or splice-affecting, 367 silent, 29 other) are not listed here.
